Somatic mutation profile of tumor specimen 0DIR3Z from CCDI case PBBWBV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.2 years (4,109 days).
Specimen 0DIR3Z: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e37d07ba-1d13-43c0-9bd1-4be95388963c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIQZR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8341fd75-ec36-4857-bb27-67f2e0717362

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CARD10 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 208/460 reads (45%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.488); catalogued as rs569899430; called by muse, mutect2, varscan2
- DBX1 | c.314C>T p.T105M | Missense Mutation (SNP) | VAF 247/546 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as COSV57053787; called by muse, mutect2, varscan2
- SEC23IP | c.1580G>T p.R527L | Missense Mutation (SNP) | VAF 194/443 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750514756; called by muse, mutect2, varscan2
- TDRD1 | c.5G>A p.S2N | Missense Mutation (SNP) | VAF 170/312 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763758347, COSV52597014; called by muse, mutect2, varscan2
- LRRC4C | c.1657C>T p.Q553* | Nonsense Mutation (SNP) | VAF 166/419 reads (40%) | called by muse, mutect2, varscan2
- SMAD9 | c.856G>A p.G286R (on ENST00000379826 / NM_001127217.3; = p.G249R on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 252/600 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO5B | c.1782T>C p.D594= | Silent (SNP) | VAF 280/616 reads (45%) | catalogued as rs753253103, COSV53226032; called by muse, mutect2, varscan2
- PDK1 | c.498C>T p.S166= | Silent (SNP) | VAF 226/547 reads (41%) | called by muse, mutect2, varscan2
- UHRF1 | c.1722C>A p.L574= (on ENST00000612630 / NM_001290050.1; = p.L587= on NM_013282.4) | Silent (SNP) | VAF 142/413 reads (34%) | catalogued as rs753189382; called by muse, mutect2, varscan2
